Somatic mutation profile of tumor specimen 0DNP4F from CCDI case PBBNSG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 6.5 years (2,387 days).
Specimen 0DNP4F: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53aa1090-141d-49e3-b7a8-a28777bc4bc9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNP4B (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c9ecaf3-8a96-48e5-935b-8ed02cc4feea

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 96/1106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2
- CCNB3 | c.1651G>A p.D551N | Missense Mutation (SNP) | VAF 13/375 reads (3%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- GABRD | c.73A>G p.M25V | Missense Mutation (SNP) | VAF 19/236 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- SPATA31D4 | c.2317A>G p.S773G | Missense Mutation (SNP) | VAF 12/342 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.61); called by muse, mutect2
- PRAG1 | c.1041C>T p.S347= | Silent (SNP) | VAF 20/238 reads (8%) | catalogued as rs918899341; called by muse, mutect2
- CAPZB | c.654+16T>C | Intron (SNP) | VAF 27/343 reads (8%) | called by muse, mutect2
